Gene-level copy-number profile of tumor specimen TARGET-40-PAVECB-01A from TARGET case TARGET-40-PAVECB, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of upper limb, scapula and associated joints; Age at diagnosis: 9.0 years (3,272 days).
Specimen TARGET-40-PAVECB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.76a6e0be-98c4-54c8-b4e0-76f29ac1ab04.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-PAVECB-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 417 have no estimate.
https://portal.gdc.cancer.gov/files/ad217c25-f628-4659-820a-fb4e702125b7

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 526; copy number 1: 157; copy number 2: 16,400; copy number 3: 16,365; copy number 4: 17,747; copy number 5: 4,696; copy number 6: 1,511; copy number 7: 1,743; copy number 8: 569; copy number 9: 39; copy number 10: 256; copy number 11: 119; copy number 12: 10; copy number 13: 55; copy number 14: 2; copy number 16: 9; copy number 18: 2.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:68,509,441–68,616,137, 4 genes: UGT2B29P, UGT2B17, AC147055.2, AC147055.4.
- chr16:78,534,374–78,553,296, 2 genes: AC046158.2, AC046158.3.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 492 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:9,943,428–9,985,501, 1 gene, copy number 9 (within-gene range 4–9): NMNAT1.
- chr1:9,967,381–10,181,239, 6 genes, copy number 9 (within-gene range 5–9): MIR5697, AL603962.1, RBP7, UBE4B, AL590639.1, PGAM1P11.
- chr1:16,974,502–17,119,451, 7 genes, copy number 9: MFAP2, AL049569.2, AL049569.1, ATP13A2, AL049569.3, SDHB, PADI2.
- chr1:17,717,625–17,827,063, 2 genes, copy number 14 (within-gene range 5–14): LINC02810, ACTL8.
- chr1:18,385,829–18,513,383, 3 genes, copy number 9: AL591896.1, KLHDC7A, DYNLL1P3.
- chr1:56,718,789–60,868,009, 44 genes, copy number 10 (within-gene range 4–10): FYB2, AL360295.1, C8A, C8B, AL161740.1, DAB1, AL390243.1, RPS20P5, DAB1-AS1, HNRNPA1P6, RPS26P15, AL445193.2, AL445193.1, AL357373.1, OMA1, AL035411.3, AL035411.2, RN7SL713P, TACSTD2, AL035411.1, MYSM1, AL136985.3, JUN, LINC01135, AL136985.2, AL136985.1, LINC02777, LINC01358, PHBP3, AL592431.2, AL592431.1, HSD52, AC093424.1, FGGY, MIR4711, AL035416.1, HOOK1, CYP2J2, RN7SL475P, C1orf87, PGBD4P8, LINC02778, LINC01748, AC099792.1.
- chr1:60,912,675–61,056,885, 1 gene, copy number 10 (within-gene range 5–10): NFIA-AS2.
- chr1:73,883,714–85,584,589, 162 genes, copy number 10–16 (broad region; genes not listed).
- chr1:150,173,049–150,780,644, 31 genes, copy number 10 (within-gene range 7–10): AC242988.2, RN7SL480P, ANP32E, RNU2-17P, AC242988.1, CA14, APH1A, C1orf54, CIART, MRPS21, PRPF3, RPRD2, TARS2, MIR6878, ECM1, FALEC, ADAMTSL4-AS2, ADAMTSL4, MIR4257, ADAMTSL4-AS1, MCL1, RN7SL473P, RN7SL600P, AL356356.1, ENSA, U4, GOLPH3L, HORMAD1, RNU6-1042P, CTSS, AL356292.1.
- chr1:152,565,654–153,113,516, 39 genes, copy number 13: LCE3E, LCE3D, LCE3C, LCE3B, LCE3A, LCEP4, LCEP3, LCE2D, LCE2C, LCE2B, LCE2A, LCE4A, C1orf68, LCEP2, LCEP1, KPRP, LCE1F, LCE1E, LCE1D, LCE1C, LCE1B, LCE1A, LCE6A, AL162596.1, SMCP, IVL, LINC01527, SPRR5, SPRR4, SPRR1A, SPRR3, AL356867.2, AL356867.1, SPRR1B, SPRR2D, SPRR2A, SPRR2B, SPRR2E, SPRR2F.
- chr1:162,979,551–163,355,764, 8 genes, copy number 10–18: AL392003.1, RGS4, RGS5, RGS5-AS1, AL451063.1, RGS5, AL592435.1, NUF2.
- chr1:243,256,034–243,500,091, 1 gene, copy number 10 (within-gene range 2–10): SDCCAG8.
- chr1:243,346,176–243,851,079, 6 genes, copy number 10: MIR4677, AKT3, AL591721.1, FABP7P1, AL662889.1, AKT3-IT1.
- chr2:83,522,814–84,819,589, 11 genes, copy number 12–16: LINC01809, RPL37P10, RNU6-1312P, CRLF3P3, ST6GALNAC2P1, FUNDC2P2, AC106874.1, SUCLG1, DNAH6, DUXAP1, LDHAP7.
- chr2:84,850,711–84,851,148, 1 gene, copy number 12: AC010087.1.
- chr2:86,720,291–88,186,636, 44 genes, copy number 10: RMND5A, CD8A, CD8B, ANAPC1P1, AC111200.1, RGPD1, WBP1P1, NDUFB4P5, PLGLB1, ANAPC1P2, ANAPC1P2, AC092651.1, AC092651.2, ANAPC1P3, AC083899.1, MIR4771-1, CENPNP1, LINC01955, DBF4P3, AC068279.2, IGKV3OR2-268, AC068279.1, LINC01943, CYTOR, AC133644.2, AC133644.1, PAFAH1B1P1, MIR4435-1, RPS14P5, ANAPC1P4, PLGLB2, RGPD2, MTATP8P2, NDUFB4P7, WBP1P2, ANAPC1P5, AC108479.2, RNU2-63P, AC108479.1, KRCC1, SMYD1, MIR4780, FABP1, THNSL2.
- chr4:36,311,190–36,426,428, 2 genes, copy number 9 (within-gene range 4–9): AC104078.2, MIR1255B1.
- chr8:69,175,579–69,178,189, 1 gene, copy number 9: AC021785.1.
- chr8:89,585,872–89,757,812, 1 gene, copy number 9 (within-gene range 6–9): AF117829.1.
- chr9:10,613,202–10,620,420, 1 gene, copy number 12: PTPRD-AS2.
- chr9:25,579,657–25,938,434, 4 genes, copy number 9: AL353730.1, TUSC1, LINC01241, FAM71BP1.
- chr9:26,642,697–27,066,134, 11 genes, copy number 9 (within-gene range 7–9): AL442639.1, AL451137.2, AL451137.1, AL356133.1, CAAP1, H3P31, RN7SL100P, PLAA, IFT74, IFT74-AS1, LRRC19.
- chr9:31,644,576–31,645,160, 1 gene, copy number 18: HMGB3P23.
- chr14:105,785,505–106,360,324, 101 genes, copy number 11 (broad region; genes not listed).
- chr21:42,346,357–42,396,091, 3 genes, copy number 9 (within-gene range 4–9): TFF2, TFF1, TMPRSS3.

Autosomal genes at a single copy (total copy number 1): 157. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
